MMRF case MMRF_2005 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7330f575-6c5b-463a-9cd6-958cc16159d9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.5 years (19,534 days); ISS stage: I; Days to last known disease status: 952 days (2.6 years); Days to last follow up: 952 days (2.6 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 149 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 151 days; Days to treatment end: 151 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 626 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 639 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 267 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -46 (ECOG 0): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.507 mg/dL; Immunoglobulin G 46.1 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 4.23 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.93 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 10 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 57 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.512 mg/dL; Immunoglobulin G 9.82 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.15 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 166 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.823 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.681 mg/dL; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.72 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 47 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 239 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.161 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.265 mg/dL; Immunoglobulin G 6.78 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 7.55 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 48 g/L; Total Protein 7.4 g/dL; Glucose 5.61 mmol/L.
- Day 323 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.638 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 4.73 mmol/L.
- Day 406 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.141 mg/dL; Immunoglobulin G 2.86 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.26 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 46 g/L; Total Protein 6.2 g/dL; Glucose 5.56 mmol/L.
- Day 491 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.955 mg/dL; Immunoglobulin G 2.43 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.81 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 582 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0312 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.125 mg/dL; Immunoglobulin G 2.07 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.
- Day 663 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.135 mg/dL; Immunoglobulin G 1.66 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 5.45 mmol/L.
- Day 757 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.238 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.221 mg/dL; Immunoglobulin G 2.21 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.13 g/L.
- Day 952 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.652 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.534 mg/dL; Immunoglobulin G 3.78 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.18 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -46: Weight: 103 kg; Height: 166 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2005_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -46 days.
- Sample MMRF_2005_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -46 days.
